Somatic mutation profile of tumor specimen TARGET-10-PAPILG-09A (aliquot TARGET-10-PAPILG-09A-01D) from TARGET case TARGET-10-PAPILG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,027 days).
Specimen TARGET-10-PAPILG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40d13b83-0fb2-4b8f-af1d-171131144f85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPILG-10A (Blood Derived Normal), aliquot TARGET-10-PAPILG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/392ab601-27e9-4a9d-b02f-e7bde6eba69a

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, 3'UTR 2, In Frame Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.3836+1G>A p.X1279_splice | Splice Site (SNP) | VAF 35/140 reads (25%) | catalogued as rs200782888, CS056749, COSV52117332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD3 | c.5320G>A p.E1774K (on ENST00000330494 / NM_001005273.3; = p.E1740K on NM_005852.4) | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as rs1403479740, COSV100177262; called by mutect2, varscan2
- DLGAP3 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.06); catalogued as rs767125526, COSV52398190; called by muse, mutect2
- DMD | c.4909G>T p.A1637S | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV63767350; called by muse, mutect2, varscan2
- FLT3 | c.2524T>A p.Y842N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54057460; called by muse, mutect2, varscan2
- TNFSF15 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758572471; called by muse, mutect2
- NPLOC4 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- SERPINH1 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SETD1B | c.5615_5616insACG p.R1872dup | In Frame Ins (INS) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- SRGAP3 | c.1177G>T p.V393L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.063); called by muse, mutect2
- XKR4 | c.78C>A p.D26E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2
- ZNF691 | c.472C>T p.R158C (on ENST00000372502; = p.R127C on NM_015911.3) | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- NCOA7 | c.1710C>A p.P570= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99997500; called by muse, mutect2
- SLC7A14 | c.1479G>A p.E493= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV51588719; called by muse, mutect2, varscan2
- VPS13B | c.1194G>A p.T398= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV62017990; called by muse, mutect2, varscan2
- GPHN | c.864+20369C>T | Intron (SNP) | VAF 23/171 reads (13%) | called by muse, mutect2, varscan2
- SPAG8 | c.*226A>G | 3'UTR (SNP) | VAF 8/22 reads (36%) | catalogued as rs1018038265; called by muse, varscan2
- TARDBP | c.*523C>A | 3'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
